Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9SY, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9SY-01A (Primary Tumor).

[page 1 of 6]
Cellular

Location

DIAGNOSIS:

CYSTECTOMY WITH URINARY DIVERSION (T-POUCH):

RIGHT DISTAL URETER (A):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER NECK MARGIN (C):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- BENIGN

FINAL DIAGNOSIS:

- BENIGN URETHRAL AND PERIURETHRAL TISSUE

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER/UTERUS, FALLOPIAN TUBES, OVARIES, PERIVESICAL LYMPH NODES (D):

BLADDER:

- POORLY DIFFERENTIATED INVASIVE UROTHELIAL CARCINOMA (4.9 X 4.7 X 1.5 CM) WITH FOCAL CLEAR CELL FEATURES, GRADE 4/4, PENETRATING THROUGH FULL THICKNESS OF BLADDER WALL INTO PERIVESICAL SOFT TISSUE
- EXTENSIVE ASSOCIATED ULCERATION PRESENT
- FOCUS OF LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- NO UROTHELIAL CARCINOMA IN SITU (FLAT LESION) SEEN IN RANDOM MUCOSA
- FOLLICULAR CYSTITIS WITH ASSOCIATED REACTIVE UROTHELIAL CHANGES
- RESECTION MARGINS, FREE OF DYSPLASIA AND MALIGNANCY

0% clear cell
per JSS

UTERUS:

- ENDOMETRIUM, FOCUS OF NONINVASIVE WELL DIFFERENTIATED ENDOMETRIAL ADENOCARCINOMA, FIGO GRADE 1/3, ARISING IN BACKGROUND OF POLYP AND ENDOMETRIUM EXHIBITING COMPLEX HYPERPLASIA WITH ATYPIA
- NO CERVICAL, MYOMETRIAL OR LYMPHOVASCULAR INVOLVEMENT IDENTIFIED
- MYOMETRIUM, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- SEROSA, ENDOSALPINGIOSIS
- CERVIX, BENIGN SQUAMOUS AND ENDOCERVICAL MUCOSA WITH NO DYSPLASIA OR MALIGNANCY IDENTIFIED
- RESECTION MARGINS, FREE OF MALIGNANCY

RIGHT AND LEFT FALLOPIAN TUBES:

- LEFT, BENIGN SIMPLE PARATUBAL CYST
- RIGHT, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- NO ATYPIA OR MALIGNANCY IDENTIFIED

RIGHT AND LEFT OVARIES:

- BILATERAL MULTIPLE SIMPLE SURFACE INCLUSION CYSTS
- NO MALIGNANCY IDENTIFIED

PERIVESICAL LYMPH NODES:

- METASTATIC UROTHELIAL CARCINOMA IDENTIFIED IN ONE OF THREE LYMPH NODES EXAMINED (0/0 RIGHT, 1/3 LEFT, 1/3 TOTAL), WITH METASTASIS 0.9 CM GREATEST

ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site Bladder NOS
path Bladder, anterior wall
C67.9
C67.4
JW 3/26/14

[page 2 of 6]
collected

RIGHT PARACAVAL LYMPH NODES (E):

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

RIGHT COMMON ILIAC LYMPH NODES (F):

- NO MALIGNANCY IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

PRESACRAL LYMPH NODES (G):

- NO MALIGNANCY IDENTIFIED IN 16 LYMPH NODES EXAMINED (0/16)
- ENDOSALPINGIOSIS

RIGHT LYMPH NODE OF CLOQUET (H):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT EXTERNAL ILIAC LYMPH NODES (I):

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (J):

- NO MALIGNANCY IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

LEFT PARA AORTIC LYMPH NODES (K):

- NO MALIGNANCY IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

LEFT COMMON ILIAC LYMPH NODES (L):

- NO MALIGNANCY IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

LEFT LYMPH NODE OF CLOQUET (M):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

LEFT EXTERNAL ILIAC LYMPH NODES (N):

- NO MALIGNANCY IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (O):

- METASTATIC UROTHELIAL CARCINOMA IDENTIFIED IN ONE OF 14 LYMPH NODES EXAMINED (1/14), WITH METASTASIS 0.4 CM GREATEST DIMENSION

RIGHT PROXIMAL URETER (P):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT PROXIMAL URETER (Q):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY: METASTATIC CARCINOMA IDENTIFIED IN TWO OF 86 LYMPH NODES EXAMINED (2/86)

PATHOLOGIC TNM STAGE: BLADDER: pT3bN2MX

COMMENT:

Representative sections of invasive urothelial carcinoma are submitted for p53

[page 3 of 6]
Collected

Location

SPECIMEN SOURCE:

- A: "RT distal ureter"
- B: "Lt. distal ureter"
- C: "Bladder neck margin"
- D: "Bladder/uterus, tubes, ovaries, peri vesicles lymph node" (sic)
- E: "Rt. para caval lymph nodes"
- F: "Rt. common iliac lymph nodes"
- G: "Pre sacral lymph nodes"
- H: "Right lymph node of cloquet"
- I: "Right external iliac lymph node"
- J: "Rt. obturator/hypogastric lymph nodes"
- K: "Lt. para aortic lymph nodes"
- L: "Lt. common iliac lymph nodes"
- M: "Lt. lymph node of cloquet"
- N: "Lt. ext. iliac lymph nodes"
- O: "Lt. obturator/hypogastric lymph nodes"
- P: "Rt. proximal ureter"
- Q: "Lt. proximal ureter"

CLINICAL INFORMATION:

Pre-Op Dx: Bladder cancer

Post-Op Dx: Same as pre-op

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labelled "RT distal ureter". It consists of a segment of ureter measuring 0.4 cm in length by 0.4 cm in diameter with attached fat. Entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labeled "Lt. distal ureter". It consists of a segment of ureter measuring 0.4 cm in length by 0.3 cm in diameter with attached fat. Entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labelled "Bladder neck margin". It consists of a ring-shaped, tan-pink soft tissue segment measuring 2.1 x 1.5 x 0.5 cm. Entirely submitted in one cassette for frozen section in cassette CFS.

D: The specimen is received fresh from the O.R. and labelled "Bladder/uterus, tubes, ovaries, peri vesicles lymph node" (sic). It consists of an anterior exenteration specimen measuring 13.5 x 12 x 5 cm overall. It includes bladder with attached bilateral ureters, cervix, uterus, bilateral fallopian tubes, bilateral ovaries and peritoneum. The peritoneum measures 7 x 12 by less than 0.1 cm. It is tan, smooth, glistening and unremarkable. The surgical margin is inked black. The bladder itself measures 6.5 x 6.5 x 5 cm. Opening the bladder anteriorly reveals an ulcerated mass located in the anterior wall and extending to the left lateral wall. It measures 4.9 x 4.7 cm in area by 1.5 cm in depth. It is 0.4 cm from the left ureterovesical junction and 2 cm from right ureterovesical junction and approximately 0.7 cm from the bladder neck margin. Grossly, it involves the full thickness of the bladder wall extending into perivesical soft tissue. It comes within approximately 0.3 cm of the anterior inked radial margin and 0.4 cm of the inked left lateral radial margin. The remainder of the mucosa is flat with patchy tan-pink areas. The involved bladder wall measures 1.8 cm in thickness. The uninvolved wall measures 0.7 cm in thickness. The attached right and left ureters measure 8 cm in length by 0.7 cm in circumference and 6.5 cm in length by 0.7 cm in circumference, respectively. Both have mucosa that is tan-pink, smooth, glistening and unremarkable without tumor involvement. The uterus with attached cervix measures 6.5 x 4.5 x 3.4 cm. The ectocervix measures 3.5 cm across. The

[page 4 of 6]
REPORT

Collected

exocervical os is slit-like measuring 1.4 cm across. Bilvalving the uterus reveals an endocervical canal measuring 2.2 cm in length and 0.9 cm in circumference. It contains tan-pink, smooth and unremarkable mucosa. The endometrial cavity measures 3.2 x 0.7 cm and contains strips of endometrium measuring 0.1 cm in average thickness. Also noted is a pedunculated endometrial polyp located on the left wall and measuring 1.8 x 0.5 x 0.3 cm. Otherwise the endometrium is unremarkable. The myometrium measures 1.7 cm in average thickness and is unremarkable. The right fallopian tube measures 7 cm in length by 0.4 to 0.8 cm in diameter, and is unremarkable. The left fallopian tube measures 7 cm in length by 0.4 to 0.8 cm in diameter. There is a thin walled cyst attached to the fimbria that measures 1 cm in diameter. The right ovary measures 2.4 x 1 x 1.1 cm. On the surface are two thin walled cysts measuring 0.3 and 0.4 cm in diameter. The sectioned ovary contains another 1.1 cm in diameter unilocular clear fluid filled cyst. Otherwise the ovary is unremarkable. The left ovary measures 2.4 x 1 x 0.8 cm with a finely nodular surface. On cross section, it contains a uniloculated fluid filled cyst measuring 0.7 cm in diameter. This ovary too is otherwise unremarkable. There is a 2 cm in dimension firm nodule identified in the left perivesical soft tissue. Representative sections are submitted in a total of 24 cassettes.

E: The specimen is received in formalin and labelled "Rt. para caval lymph nodes". It consists of a 3.3 x 1.6 x 0.6 cm segment of fibrofatty tissue containing lymph nodes measuring 2.6 x 0.6 x 0.5 cm. The entire specimen is submitted in one cassette.

F: The specimen is received in formalin and labelled "Rt. common iliac lymph nodes". It consists of multiple segments of yellow fatty tissue measuring 3.7 x 3.7 x 1 cm in aggregate. It contains multiple lymph nodes ranging from 0.8 cm to 2.8 cm in greatest dimension. The entire tissue is submitted in two cassettes.

G: The specimen is received in formalin and labelled "Pre sacral lymph nodes". It consists of a 5.7 x 3 x 0.8 cm segment of fibrofatty tissue entirely submitted in three cassettes.

H: The specimen is received in formalin and labelled "Right lymph node of cloquet". It consists of a 3 x 2.2 x 0.6 cm segment of yellow lobulated fatty tissue. Entirely submitted in one cassette.

I: The specimen is received in formalin and labelled "Right external iliac lymph node". It consists of two segments of yellow lobulated fatty tissue measuring 4.7 x 4 x 1 cm in aggregate. It contains multiple lymph nodes ranging from 0.6 to 1.1 cm in greatest dimension. Entirely submitted in two cassettes.

J: The specimen is received in formalin and labelled "Rt. obturator/hypogastric lymph nodes". It consists of multiple segments of yellow fatty tissue containing multiple lymph nodes ranging from 0.6 to 2.5 cm in greatest dimension. The entire tissue is submitted in two cassettes.

K: The specimen is received in formalin and labelled "Lt. para aortic lymph nodes". It consists of a 2.2 x 1.6 x 0.5 cm segment of fibrofatty tissue. Entirely submitted in one cassette.

L: The specimen is received in formalin and labelled "Lt. common iliac lymph nodes". It consists of a 4 x 2.6 x 0.7 cm segment of yellow fatty tissue containing multiple lymph nodes ranging from 0.4 cm to 1.2 cm in greatest dimension. Entirely submitted in two cassettes.

M: The specimen is received in formalin and labelled "Lt. lymph node of cloquet". It consists of a 2.6 x 2.1 x 1.2 cm segment of yellow fatty tissue. Entirely submitted in one cassette.

[page 5 of 6]
... The specimen is received in formalin and labelled "Lt. ext. iliac lymph nodes". It consists of a 7 x 1.1 x 0.9 cm segment of fibrofatty tissue containing multiple lymph nodes which range from 0.7 to 1 cm in greatest dimension. The entire tissue is submitted in two cassettes.

O: The specimen is received in formalin and labelled "Lt. obturator/hypogastric lymph nodes". It consists of a 5.5 x 4 x 1.6 cm segment of fatty tissue containing multiple lymph nodes ranging from 0.3 cm to 2.3 cm in greatest dimension. The entire tissue is submitted in four cassettes.

P: The specimen is received in formalin and labelled "Rt. proximal ureter". It consists of a segment of ureter measuring 0.7 cm in length by 0.4 cm in diameter with attached adipose tissue. Bisected and entirely submitted in one cassette.

Q: The specimen is received in formalin and labelled "Lt. proximal ureter". It consists of a segment of ureter measuring 0.5 cm in length by 0.4 cm in diameter, with attached adipose tissue. Bisected and entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
CFS: frozen section, bladder neck margin
D1,2: anterior wall towards right
D3: left anterior wall
D4: right lateral wall
D5: right ureterovesical junction
D6: dome
D7: posterior wall
D8: left ureterovesical junction
D9-11: left lateral wall with ulcerated mass
D12: trigone and bladder neck
D13: bladder neck margin to ulcerated mass, left side
D14: bladder neck margin to ulcerated mass, right side
D15: anterior cervix and uterine wall
D16: posterior cervix and uterine wall with endometrial polyp
D17: endometrial polyp
D18: right fallopian tube, ovary and ureter
D19: left fallopian tube, ovary and ureter
D20: possible right perivesical lymph nodes
D21-23: largest left perivesical nodule, quadrisection
D24: possible left perivesical lymph nodes
E: right paracaval lymph nodes - all embedded
F1,2: right common iliac lymph nodes - all embedded
G1-3: presacral lymph nodes - all embedded
H: right lymph node of Cloquet - all embedded
I1: right external iliac lymph node; lymph node
I2: remaining tissue
J1: right obturator/hypogastric lymph nodes; largest lymph node
J2: remaining tissue and lymph node
K: left para-aortic lymph nodes - all embedded
L1,2: left common iliac lymph nodes - all embedded
M: left lymph node of Cloquet
N1: left ext. iliac lymph nodes; lymph nodes
N2: remaining tissue
O1,2: left obturator/hypogastric lymph nodes; multiple lymph nodes
O3: largest lymph node, bisected
O4: remaining tissue
P: right proximal ureter - all embedded
Q: left proximal ureter - all embedded

[page 6 of 6]
Collected

Location

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter:

- no high-grade atypia or tumor identified

BFS: Left distal ureter:

- no high-grade atypia or tumor identified

CFS: Bladder neck margin:

- no high-grade atypia or tumor identified

MICROSCOPIC EXAMINATION:

A-C: See final microscopic-diagnosis.

D: Sections of the bladder show a poorly differentiated invasive urothelial carcinoma (D1-3,9-11,13,14), grade 4/4, with focal clear features. The carcinoma is associated with extensive ulceration and penetrates through the bladder wall into perivesical soft tissue (D1,2,10,11). A focus of lymphovascular space invasion is seen (D13). Carcinoma comes within 0.5 cm of the anterior radial margin and 1.2 cm of the bladder neck margin. All other radial margins and bilateral ureters margins are more widely free of malignancy. No trigone or ureterovesical junction involvement by dysplasia or malignancy is seen. Metastatic urothelial carcinoma is identified in one of three left perivesical lymph nodes examined (D21-23).

Sections of the uterus show a small focus of well differentiated endometrial adenocarcinoma, FIGO grade 1/3, arising in association with endometrium and a polyp containing complex endometrial hyperplasia with atypia (D15-17). No myometrial or cervical invasion is identified. All surgical margins are free of malignancy.

E-Q: See final microscopic-diagnosis.

Source: NCI Genomic Data Commons file 0686e591-5f01-479c-9235-0ad12e635347 (TCGA-XF-A9SY.FACDA2AA-EE41-4EF5-8599-E72249E4B715.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).